Gene-level copy-number profile of tumor specimen TCGA-IN-A7NR-01A from TCGA case TCGA-IN-A7NR, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 64.1 years (23,415 days).
Specimen TCGA-IN-A7NR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.12ec97b5-4901-4edd-87ee-ee34f07eaef4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IN-A7NR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6f3f5e60-bdb9-4b0e-a4c3-d749275486f2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 2: 58,919; copy number 3: 784; copy number 4: 46; copy number 5: 56; copy number 6: 1; copy number 10: 8; copy number 11: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IN-A7NR-01A-11D-A34T-01): tumor purity 0.2, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 70 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:87,226,189–87,595,376, 5 genes, copy number 11: MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2.
- chr8:126,174,186–130,017,129, 55 genes, copy number 5: RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, AC103718.1, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194.
- chr8:130,069,541–130,069,652, 1 gene, copy number 5: RNU6-1255P.
- chr8:137,105,352–137,105,458, 1 gene, copy number 6: RNU6-144P.
- chr12:25,195,216–25,409,445, 7 genes, copy number 10: ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1.
- chr12:25,423,600–25,424,942, 1 gene, copy number 10: AC092451.2.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
